Somatic mutation profile of tumor specimen 0DRHQ3 from CCDI case PBCGLD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Germinoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.8 years (4,301 days).
Specimen 0DRHQ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4af87cb-c11b-405d-869f-2db83dfb3756.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRHQ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d804c8b-91b5-4311-9c67-60502c3271ce

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Nonsense Mutation 1, 5'UTR 1, Silent 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEFH | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 895/1952 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as rs377149236; called by muse, mutect2, varscan2
- SMARCC2 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 97/714 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1225976444; called by muse, mutect2, varscan2
- CDH17 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 103/1032 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP27C1 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 119/1119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ESPNL | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 63/531 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- IL23R | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 279/775 reads (36%) | called by muse, mutect2, varscan2
- ITPR1 | c.6952C>T p.L2318F (on ENST00000354582; = p.L2263F on NM_002222.7) | Missense Mutation (SNP) | VAF 136/917 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- LAMP2 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 61/336 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCN9A | c.4723A>G p.T1575A (on ENST00000303354; = p.T1564A on NM_002977.3) | Missense Mutation (SNP) | VAF 273/949 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- NHLRC3 | c.540G>A p.V180= | Silent (SNP) | VAF 76/633 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.494-58G>A | Intron (SNP) | VAF 44/196 reads (22%) | called by muse, mutect2, varscan2
- NEB | c.18826-3062C>T | Intron (SNP) | VAF 70/225 reads (31%) | catalogued as rs764635163; called by muse, mutect2, varscan2
- SLC35F1 | c.-237C>T | 5'UTR (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
